Somatic mutation profile of tumor specimen C3N-01493-04 (aliquot CPT0106070006) from CPTAC case C3N-01493, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 35.0 years (12,770 days).
Specimen C3N-01493-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f87967e-e7fb-4e09-8d69-61582d41d4a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01493-31 (Blood Derived Normal), aliquot CPT0110050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a04eaabb-a145-4d1e-b2f9-1ef01752909a

The open-access MAF lists 116 somatic variants for this specimen: 80 protein-altering or splice-affecting, 30 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 30, Nonsense Mutation 7, Intron 4, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/370 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACADM | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs368385016; called by muse, varscan2
- ACOT12 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 173/446 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs868792940; called by muse, mutect2, varscan2
- ADNP | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 229/761 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs1045825663; called by muse, mutect2, varscan2
- ANKRD30B | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 236/634 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs267605123; called by muse, mutect2, varscan2
- ATP10D | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 195/477 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.103); catalogued as rs149671949; called by muse, mutect2, varscan2
- CANT1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 258/554 reads (47%) | catalogued as rs372332465; called by muse, mutect2, varscan2
- CEP112 | c.317C>G p.P106R | Missense Mutation (SNP) | VAF 161/407 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101210690; called by muse, mutect2, varscan2
- COLEC12 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 247/653 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474498152; called by muse, mutect2, varscan2
- CYP27B1 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 1080/1306 reads (83%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as rs1157396007; called by muse, varscan2
- DNAH7 | c.5620C>T p.R1874* | Nonsense Mutation (SNP) | VAF 134/325 reads (41%) | catalogued as rs267599141, COSV56755304; called by muse, mutect2, varscan2
- F13A1 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 164/597 reads (27%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.574); catalogued as rs367893759; called by muse, mutect2
- FBXL19 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 379/807 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs561775075; called by muse, mutect2, varscan2
- FBXO27 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 205/508 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.188); catalogued as COSV53072693; called by muse, mutect2, varscan2
- FIGNL1 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 159/390 reads (41%) | catalogued as rs763712899; called by muse, mutect2, varscan2
- GALNT13 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 190/455 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366785930, COSV67231091; called by muse, mutect2, varscan2
- GIMAP8 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 237/500 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV56229625; called by muse, mutect2, varscan2
- GPR83 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 153/311 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147783996; called by muse, mutect2, varscan2
- IGKV1D-16 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 198/550 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as rs369645871; called by muse, mutect2, varscan2
- IVL | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 263/889 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV64217228; called by mutect2, varscan2
- KIF18A | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 143/339 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754298032; called by muse, mutect2, varscan2
- LDB2 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 279/639 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV58772369; called by muse, mutect2, varscan2
- MMRN1 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 171/384 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV53335214; called by muse, mutect2, varscan2
- MUC5AC | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 120/294 reads (41%) | SIFT deleterious (0); catalogued as COSV62254473; called by muse, mutect2, varscan2
- OR2A12 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 108/297 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV68821806; called by muse, mutect2, varscan2
- OR4F5 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 297/318 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs200013390, COSV58737103; called by muse, mutect2, varscan2
- PDE7B | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 184/235 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs760504959; called by muse, mutect2, varscan2
- PRPS1L1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 199/478 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV72649864; called by muse, mutect2, varscan2
- RDH8 | c.875C>T p.S292F (on ENST00000651512; = p.S272F on NM_015725.4) | Missense Mutation (SNP) | VAF 228/547 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV50679058; called by muse, mutect2, varscan2
- RICTOR | c.2393G>C p.G798A | Missense Mutation (SNP) | VAF 207/495 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57119378; called by muse, mutect2, varscan2
- SCRN3 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs941277355, COSV99767118; called by muse, mutect2, varscan2
- SEC23A | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 192/497 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs1484342490, COSV56972727; called by muse, mutect2, varscan2
- SIK2 | c.2329G>A p.V777I | Missense Mutation (SNP) | VAF 306/708 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as rs1431896790, COSV59250320; called by muse, mutect2, varscan2
- SULT2B1 | c.661G>A p.V221M (on ENST00000201586 / NM_177973.2; = p.V206M on NM_004605.2) | Missense Mutation (SNP) | VAF 180/418 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs771791526, COSV52376444; called by muse, varscan2
- TAF2 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 253/589 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs763580911, COSV65419002; called by muse, mutect2, varscan2
- UGT2B17 | c.1457G>A p.W486* | Nonsense Mutation (SNP) | VAF 303/352 reads (86%) | catalogued as COSV100497174, COSV58502577; called by muse, mutect2, varscan2
- XAB2 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 209/455 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs1304347185, COSV50330847; called by muse, mutect2, varscan2
- YAF2 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 400/726 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV59891732; called by muse, mutect2
- ZNF90 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 175/513 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV69002490; called by muse, mutect2, varscan2
- ABCC6 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 198/741 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTR2 | c.176A>C p.D59A | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- C11orf97 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 189/428 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CA10 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 126/265 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CEP76 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- CHD8 | c.2423G>A p.R808K (on ENST00000646647 / NM_001170629.2; = p.R529K on NM_020920.4) | Missense Mutation (SNP) | VAF 184/397 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- COL6A3 | c.5768A>T p.Y1923F | Missense Mutation (SNP) | VAF 216/491 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EEF1AKMT3 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 2049/2477 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ESF1 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 182/382 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAF2 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 258/569 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- FGR | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 233/613 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIA1 | c.2710A>G p.T904A | Missense Mutation (SNP) | VAF 93/232 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- HRNR | c.5273A>G p.E1758G | Missense Mutation (SNP) | VAF 111/1354 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.13393G>A p.E4465K | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- IGHE | c.1041C>G p.I347M | Missense Mutation (SNP) | VAF 259/1028 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- IGHE | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 157/690 reads (23%) | called by muse, mutect2, varscan2
- IVL | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 315/999 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- JPH1 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 250/620 reads (40%) | called by muse, mutect2, varscan2
- LLGL2 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 255/633 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- MAP3K13 | c.2087C>A p.P696H | Missense Mutation (SNP) | VAF 77/410 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEGF6 | c.4555C>A p.Q1519K | Missense Mutation (SNP) | VAF 238/516 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYH1 | c.3369G>T p.E1123D | Missense Mutation (SNP) | VAF 225/490 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MYO1A | c.2441G>A p.S814N | Missense Mutation (SNP) | VAF 504/821 reads (61%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO3A | c.3914A>C p.K1305T | Missense Mutation (SNP) | VAF 211/257 reads (82%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- MYOF | c.4192G>A p.D1398N | Missense Mutation (SNP) | VAF 186/253 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NUP42 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 158/364 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- NXN | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OR2A12 | c.653T>G p.L218W | Missense Mutation (SNP) | VAF 260/565 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PCSK4 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 200/472 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- PHTF1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 232/521 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PZP | c.2998C>A p.Q1000K | Missense Mutation (SNP) | VAF 188/468 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- RALGAPA2 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 44/526 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2
- RGPD3 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RGSL1 | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 210/368 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCFD1 | c.1570A>G p.M524V | Missense Mutation (SNP) | VAF 131/364 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SEZ6L2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 222/492 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SORCS3 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 144/167 reads (86%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 259/331 reads (78%) | SIFT tolerated (0.22); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SV2C | c.448T>A p.F150I | Missense Mutation (SNP) | VAF 250/541 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YAF2 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 314/520 reads (60%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF648 | c.1170G>C p.K390N | Missense Mutation (SNP) | VAF 310/1013 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- A2M | c.111C>T p.S37= | Silent (SNP) | VAF 166/411 reads (40%) | called by muse, mutect2, varscan2
- ADGRV1 | c.2127C>T p.P709= | Silent (SNP) | VAF 260/591 reads (44%) | called by muse, mutect2, varscan2
- CALN1 | c.63C>G p.L21= (on ENST00000329008 / NM_001017440.3; = p.L63= on NM_031468.4) | Silent (SNP) | VAF 219/499 reads (44%) | called by muse, mutect2, varscan2
- CEACAM7 | c.603C>T p.L201= | Silent (SNP) | VAF 228/499 reads (46%) | catalogued as rs199809426, COSV50072688; called by muse, mutect2, varscan2
- COL25A1 | c.24G>A p.G8= | Silent (SNP) | VAF 234/583 reads (40%) | catalogued as COSV67649814; called by muse, varscan2
- CSMD2 | c.8718C>T p.F2906= | Silent (SNP) | VAF 154/416 reads (37%) | called by muse, mutect2, varscan2
- FIGNL1 | c.999C>T p.S333= | Silent (SNP) | VAF 162/393 reads (41%) | catalogued as COSV63554111; called by muse, mutect2, varscan2
- IGHE | c.690C>T p.F230= | Silent (SNP) | VAF 200/880 reads (23%) | called by muse, varscan2
- LAMC2 | c.1548C>T p.P516= | Silent (SNP) | VAF 462/748 reads (62%) | called by muse, mutect2, varscan2
- MAOA | c.1233C>T p.F411= | Silent (SNP) | VAF 237/267 reads (89%) | called by muse, mutect2, varscan2
- NLRP5 | c.984G>A p.K328= | Silent (SNP) | VAF 248/546 reads (45%) | catalogued as COSV66766419; called by muse, mutect2, varscan2
- NT5C1B | c.597C>T p.P199= (on ENST00000359846 / NM_001199086.2; = p.P139= on NM_033253.4) | Silent (SNP) | VAF 264/657 reads (40%) | called by muse, varscan2
- OBSCN | c.10749C>T p.S3583= | Silent (SNP) | VAF 163/614 reads (27%) | called by muse, mutect2, varscan2
- OBSCN | c.10750C>T p.L3584= | Silent (SNP) | VAF 164/610 reads (27%) | catalogued as COSV99483141; called by muse, mutect2, varscan2
- PCSK4 | c.1177C>T p.L393= | Silent (SNP) | VAF 160/377 reads (42%) | called by muse, varscan2
- PLXNA2 | c.3012C>T p.I1004= | Silent (SNP) | VAF 190/637 reads (30%) | catalogued as rs772163887, COSV65443513; called by muse, mutect2, varscan2
- PSG1 | c.765G>A p.K255= | Silent (SNP) | VAF 229/608 reads (38%) | catalogued as rs1207306693, COSV54960217; called by muse, mutect2, varscan2
- RUNDC3B | c.837C>T p.T279= | Silent (SNP) | VAF 118/245 reads (48%) | catalogued as rs780795544; called by muse, mutect2, varscan2
- RUSC2 | c.2929C>T p.L977= | Silent (SNP) | VAF 230/286 reads (80%) | called by muse, mutect2, varscan2
- SCARF1 | c.894G>A p.L298= | Silent (SNP) | VAF 317/774 reads (41%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.285C>T p.L95= | Silent (SNP) | VAF 265/556 reads (48%) | catalogued as rs564375018; called by muse, mutect2, varscan2
- TOX2 | c.1011C>T p.F337= (on ENST00000358131 / NM_001098798.2; = p.F313= on NM_032883.3) | Silent (SNP) | VAF 367/1102 reads (33%) | catalogued as COSV57883894; called by muse, mutect2, varscan2
- TRAV8-3 | c.207C>T p.Y69= | Silent (SNP) | VAF 174/423 reads (41%) | called by muse, mutect2, varscan2
- TRAV9-1 | c.111C>T p.S37= | Silent (SNP) | VAF 211/496 reads (43%) | catalogued as rs1436523567; called by muse, mutect2, varscan2
- TRIM10 | c.519C>T p.V173= | Silent (SNP) | VAF 254/464 reads (55%) | catalogued as rs1454336667; called by muse, mutect2, varscan2
- TTN | c.1365G>A p.T455= | Silent (SNP) | VAF 185/439 reads (42%) | catalogued as rs145211131; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- WIZ | c.633C>T p.P211= | Silent (SNP) | VAF 196/533 reads (37%) | catalogued as rs933792498; called by muse, mutect2, varscan2
- ZDHHC4 | c.595T>C p.L199= | Silent (SNP) | VAF 163/406 reads (40%) | called by muse, mutect2, varscan2
- ZNF236 | c.1290C>T p.S430= | Silent (SNP) | VAF 264/608 reads (43%) | catalogued as rs574501723; called by muse, mutect2, varscan2
- ZNF710 | c.654C>T p.F218= | Silent (SNP) | VAF 316/704 reads (45%) | catalogued as rs368466206; called by muse, varscan2
- ANKRD44 | c.2924-1117C>T | Intron (SNP) | VAF 168/409 reads (41%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6007C>T | Intron (SNP) | VAF 215/458 reads (47%) | called by muse, mutect2, varscan2
- LRRC74B | c.415+46C>T | Intron (SNP) | VAF 65/135 reads (48%) | called by muse, mutect2, varscan2
- MBP | c.576+6924G>A | Intron (SNP) | VAF 243/532 reads (46%) | called by muse, mutect2, varscan2
- NAXD | chr13:110615609 T>G | 5'Flank (SNP) | VAF 260/618 reads (42%) | called by muse, mutect2, varscan2
- PKD1L2 | n.133G>A | RNA (SNP) | VAF 175/434 reads (40%) | catalogued as rs772620770; called by muse, mutect2, varscan2
